FM case AD818 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Germ Cell Neoplasms; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/f65db06b-c1d5-48e0-8a1e-d61ae7c7efba

Male, 34.5 years: Germ cell tumor, NOS (ICD-O-3 9064/3) of the testis; metastasis biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
